Somatic mutation profile of tumor specimen 0DVCF6 from CCDI case PBCMBZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,292 days).
Specimen 0DVCF6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e823152-2bb6-45f2-9906-ab30b46add52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa929ca2-5ca6-4e4d-86a7-0e75b7f40cbb

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 2, Silent 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT2 | c.575_578del p.L192Rfs*55 | Frame Shift Del (DEL) | VAF 94/414 reads (23%) | catalogued as rs1467323413; called by mutect2, varscan2
- CCSER1 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 240/525 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs775741786, COSV100388301, COSV100390100; called by muse, mutect2, varscan2
- CHRM5 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 159/424 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226004026; called by muse, mutect2, varscan2
- FOXO3 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1349431368, COSV100670203; called by muse, mutect2, varscan2
- HELQ | c.3139G>T p.V1047L | Missense Mutation (SNP) | VAF 62/1100 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV55025428, COSV55026087; called by muse, mutect2
- KEL | c.1017C>G p.D339E | Missense Mutation (SNP) | VAF 139/1198 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV62338539; called by muse, mutect2, varscan2
- KIAA0100 | c.4756G>A p.V1586I | Missense Mutation (SNP) | VAF 53/460 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as rs1363556082; called by muse, mutect2, varscan2
- MAPK15 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 50/493 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs782319299, COSV62027866; called by muse, mutect2, varscan2
- TNRC18 | c.3400C>T p.R1134C | Missense Mutation (SNP) | VAF 85/343 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs573935644; called by muse, mutect2, varscan2
- AHR | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); called by mutect2, varscan2
- ALKBH1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 13/442 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); called by muse, mutect2
- ALKBH1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 13/435 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); called by muse, mutect2
- ALLC | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 42/774 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 58/1746 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- SELENOI | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 56/883 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- SLC6A15 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 120/669 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZHX2 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 68/791 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO16 | c.9C>T p.I3= | Silent (SNP) | VAF 63/1178 reads (5%) | catalogued as rs1288602664, COSV51821096; called by muse, mutect2
- ZNF138 | c.579T>C p.N193= (on ENST00000307355 / NM_001367572.1; = p.N167= on NM_006524.4) | Silent (SNP) | VAF 108/478 reads (23%) | called by muse, mutect2, varscan2
- AADAC | c.603+26T>A | Intron (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- CTSF | c.1381-12C>T | Intron (SNP) | VAF 39/345 reads (11%) | catalogued as rs1300554440; called by muse, mutect2, varscan2
- MFSD4B | c.-52C>T | 5'UTR (SNP) | VAF 33/254 reads (13%) | catalogued as rs1325920327; called by muse, mutect2, varscan2
